Surgical pathology report (de-identified scan), TCGA case TCGA-HZ-A4BH, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HZ-A4BH-01A (Primary Tumor).

[page 1 of 3]
Sex:M

BD:

MR#:

SURGICAL PATHOLOGY

SURGERY CASE #: FINAL

DATE OF SURGERY:

SURGEON:

SPECIMEN:

- A. Whipple with margins.
- B. Gallbladder and contents.

FROZEN SECTION DIAGNOSIS: A. Common bile duct surgical margin free of tumor.
Pancreatic margin focally involved by tumor.

OPERATIVE PROCEDURE: Whipple procedure.
PREOPERATIVE DIAGNOSIS: None given.
POSTOPERATIVE DIAGNOSIS: None given.

*****DIAGNOSIS*****

A, B.

1. Type of specimen:
Pancreaticoduodenectomy (Whipple resection) and cholecystectomy.
2. Tumor type:
Pancreatic ductal adenocarcinoma.
3. Histologic grade:
Moderately to poorly differentiated.
4. Tumor size:
2.5 cm, extending into peripancreatic soft tissue.
5. Surgical margins:
Pancreatic surgical involved by tumor.
Tumor extends to inked soft tissue margin.
All other surgical margins free of tumor.
6. Venous (large vessel) invasion:
Absent.
7. Lymphatic (small vessel) invasion:
Present.
8. Perineural invasion:
Present.
9. Lymph nodes:
Total number of lymph nodes examined: 10.
Number of lymph nodes involved: 4 (4/10).
Focal extracapsular extension identified.
10. Additional pathologic findings:
Chronic pancreatitis.
Acute and chronic cholecystitis.
Cholelithiasis.

ICD - 0 - 3
adenocarcinoma, duct 8500/3
Site: pancreas, head c25.0

hw
9/26/12

[page 2 of 3]
11. TNM STAGING:
pT3, pN1b, pMX
(See previous

MICROSCOPIC EXAMINATION:

- A. Multiple sections are examined and sections of the pancreatic mass grossly described demonstrates an invasive malignant epithelial neoplasm. The tumor demonstrates medium size to small glands as well as small nests of cells that are lined by cells containing a moderate amount of cytoplasm with enlarged pleomorphic nuclei with prominent nucleoli. A desmoplastic stromal response surrounds the tumor. The neoplasm is seen involving the pancreatic surgical margin with the sections immediately taken adjacent to the margin extensively involved by tumor. The tumor is also seen involving the peripancreatic soft tissue and involving the inked uncinate (retroperitoneal) soft tissue margin. There is perineural invasion and a focus of lymphatic invasion is noted. There is no definite venous (large vessel) invasion. The adjacent pancreas demonstrates chronic inflammation and fibrosis. The common bile duct margin is free of tumor. No involvement of the overlying small bowel or ampulla of Vater is seen, the latter demonstrating mucosal ulceration with acute and chronic inflammation and hemorrhage with foreign body multinucleated giant cell reaction. Sections taken from the gastric and small bowel mucosal surgical margins are unremarkable, with no malignancy. Random sections of the stomach demonstrate no significant distortion of the overall glandular architecture with no *Helicobacter pylori* identified on special stain (Giemsa). Random sections taken from the stomach, pylorus and small bowel are also unremarkable. There are a total of ten lymph nodes identified, four of which (peripancreatic) are involved by metastatic adenocarcinoma with focal extracapsular extension identified.
- B. Sections are of gallbladder with mild acute and chronic inflammation. There is no malignancy.

GROSS:

- A. Received labeled "Whipple" is a 13 cm segment of stomach in continuity with small bowel measuring 14 cm and head of pancreas measuring 5 cm, with surrounding soft tissue. Present on the head of the pancreas is a firm mass measuring 2.5 cm maximally. The tumor appears to closely approach the pancreatic margin, and grossly is also seen involving the uncinate (retroperitoneal/mesopancreatic) soft tissue margin. The stomach is opened along the greater curvature and small bowel along the antimesenteric side. The ampulla of Vater is erythematous with metal clips present on the mucosa. The tumor does not grossly involve the ampulla or small bowel mucosa. The gastric mucosa and small bowel mucosa appear unremarkable and the pylorus also appears unremarkable. The remainder of the pancreas demonstrates a lobulated, yellow parenchyma. Representative section of the tumor is submitted for Genomics Project. The pancreatic duct and parenchymal surgical margin are submitted for frozen section and frozen section diagnosis in block #1, and the common bile duct margin is submitted for frozen section and frozen section diagnosis in block #2. Representative section of the tumor is also submitted for chemosensitivity assay. Sections are then submitted for permanent as follows: Cassette #3 - Sections immediately adjacent to the

[page 3 of 3]
pancreatic duct surgical margin. #4 through #8 - Additional sections of tumor with #5, #6, and #7 containing inked soft tissue margin. #9 - Pancreas and overlying small bowel. #10 - Immediately adjacent pancreas. #11 and #12 - Sections of ampulla of Vater. #13 - Small peripancreatic lymph nodes. #14 - Proximal and distal mucosal (gastric and small bowel) margins. #15 - Random sections of stomach. #16 - Sections of stomach, pylorus and small bowel. #17 and #18 - Additional peripancreatic lymph nodes. #19 - Lymph nodes from lesser curvature. #20 and #21 - Lymph nodes from greater curvature. [REDACTED]

- B. Received in Formalin labeled with the patient's name, account number, and "gallbladder and contents" is a gallbladder measuring 7 cm in length x 4 cm in maximum diameter. The serosal surface is pink-tan and diffusely hemorrhagic. The cystic duct is patent. A cystic duct lymph node is not identified. The specimen is opened to reveal a large amount of green-tan bile and two bile stones ranging in size from 0.4 to 0.5 cm maximally. The mucosal surface is pale tan, smooth and velvety. The wall measures 0.3 cm thick. Representative sections are submitted in a single cassette. [REDACTED]

Electronically Signed by
[REDACTED]

Dictated: Job# [REDACTED]
Transcribed: Doc# [REDACTED]

cc: [REDACTED] MD
[REDACTED] MD
[REDACTED] MD
[REDACTED] MD

8/31/12

Source: NCI Genomic Data Commons file 0f3043c3-7678-42de-8c34-8ec9f07962c4 (TCGA-HZ-A4BH.7531D241-8782-4947-A4A5-E78F4D821A84.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).